Gene-level copy-number profile of tumor specimen TCGA-CJ-5689-01A from TCGA case TCGA-CJ-5689, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-CJ-5689-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.2427b22b-a197-4544-b9a1-2833baf97eaa.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 4,801 have no estimate.
https://portal.gdc.cancer.gov/files/5a8cf0d1-c824-4cc5-96c9-29e918cf5311

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,548; copy number 2: 46,357; copy number 3: 1,917.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CJ-5689-01A-11D-1530-01): tumor purity 0.46, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,548. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
